MMRF case MMRF_1923 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6384a5a9-7dc6-48f2-80b1-acb7b20978f0

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.0 years (19,366 days); ISS stage: I; Days to last known disease status: 990 days (2.7 years); Days to last follow up: 990 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 162 days.
   Treatment given: Therapeutic agents: Daratumumab + Dexamethasone + Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 152 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 171 days; Days to treatment end: 171 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 173 days; Days to treatment end: 173 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 318 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -12 (ECOG 0): M Protein 3.61 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 10.9 mg/dL; Immunoglobulin G 57.6 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 2.39 µg/mL; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 4.08 ×10⁹/L; Absolute Neutrophil 1.99 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.23 mmol/L; Albumin 46.2 g/L; Total Protein 9.6 g/dL; Glucose 4.73 mmol/L; C-Reactive Protein 0.006 mg/dL.
- Day 64 (ECOG 0): Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.23 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 293 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.15 mmol/L; Albumin 34.5 g/L; Total Protein 5.6 g/dL; Glucose 3.96 mmol/L.
- Day 162 (ECOG 0): M Protein 0.28 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.41 mg/dL; Immunoglobulin G 7.06 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 3.94 ×10⁹/L; Absolute Neutrophil 2.72 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.28 mmol/L; Albumin 40.2 g/L; Total Protein 6.1 g/dL; Glucose 4.79 mmol/L.
- Day 254 (ECOG 0): M Protein 0.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.00616 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.61 mg/dL; Immunoglobulin G 6.04 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4.16 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.38 mmol/L; Albumin 41.9 g/L; Total Protein 6 g/dL.
- Day 346 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.76 mg/dL; Immunoglobulin G 6.86 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.51 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.45 mmol/L; Albumin 43.9 g/L; Total Protein 6.4 g/dL; Glucose 3.25 mmol/L.
- Day 430 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.784 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.833 mg/dL; Immunoglobulin G 7 g/L; Immunoglobulin A 4.37 g/L; Immunoglobulin M 5.09 g/L; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.87 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 4.57 mmol/L.
- Day 542 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.833 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.979 mg/dL; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.62 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 4.82 mmol/L; Calcium 2.3 mmol/L; Albumin 41.3 g/L; Total Protein 6.3 g/dL; Glucose 4.84 mmol/L.
- Day 626 (ECOG 0): M Protein 0.3 g/dL; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.77 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5.53 mmol/L; Calcium 2.45 mmol/L; Albumin 40.8 g/L; Total Protein 6.6 g/dL; Glucose 5.01 mmol/L.
- Day 710 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.65 mg/dL; Immunoglobulin G 9.1 g/L; Immunoglobulin A 0.78 g/L; Immunoglobulin M 0.68 g/L; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.86 mmol/L; Calcium 2.33 mmol/L; Albumin 43.4 g/L; Total Protein 6.8 g/dL; Glucose 5.06 mmol/L.
- Day 794 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Immunoglobulin G 9.08 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 0.7 g/L; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.78 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 48.6 g/L; Total Protein 7.1 g/dL; Glucose 5.06 mmol/L.
- Day 878 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 9.93 g/L; Immunoglobulin A 0.9 g/L; Immunoglobulin M 0.72 g/L; Lactate Dehydrogenase 3.6 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 11.5 ×10⁹/L; Absolute Neutrophil 8.7 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.83 mmol/L; Calcium 2.3 mmol/L; Albumin 45.7 g/L; Total Protein 6.8 g/dL; Glucose 5.01 mmol/L.
- Day 990 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 8.82 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.68 g/L; Beta 2 Microglobulin 0.72 µg/mL; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.41 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.5 mmol/L; Calcium 2.35 mmol/L; Albumin 48.6 g/L; Total Protein 7.1 g/dL; Glucose 4.95 mmol/L.

Other clinical attributes
- Day -12: Weight: 70 kg; Height: 169 cm.

Biospecimens (2 samples)
- Sample MMRF_1923_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -12 days.
- Sample MMRF_1923_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -12 days.
